CCDI case PBCVMN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/1d9a0c50-b9e4-439e-a03b-93f3d46fcdef

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E0UHK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E0UHZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E0UI5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
